Somatic mutation profile of tumor specimen 0DVM1L from CCDI case PBCLXG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0DVM1L: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a5092e6-6d98-414a-9c8f-9ece1f3a10d4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVM1O (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4450b86e-8292-4cf1-b429-aa2a99e04e32

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 8, Silent 2, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 251/774 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- DNAH3 | c.5359C>T p.R1787C | Missense Mutation (SNP) | VAF 69/521 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146173789; called by muse, mutect2, varscan2
- FCGBP | c.5971G>A p.A1991T | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.137); catalogued as rs762016591, COSV55444020; called by muse, varscan2
- GSE1 | c.2200C>T p.R734W | Missense Mutation (SNP) | VAF 67/196 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765265161, COSV53673092; called by muse, mutect2, varscan2
- DOCK3 | c.4992G>A p.M1664I | Missense Mutation (SNP) | VAF 16/446 reads (4%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2
- HR | c.762G>T p.E254D | Missense Mutation (SNP) | VAF 36/244 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- MARCHF1 | c.409A>C p.K137Q (on ENST00000274056; = p.K120Q on NM_017923.4) | Missense Mutation (SNP) | VAF 152/491 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- MBD2 | c.473del p.G158Dfs*7 | Frame Shift Del (DEL) | VAF 70/239 reads (29%) | called by mutect2, varscan2
- PCDHGA7 | c.1561G>C p.D521H | Missense Mutation (SNP) | VAF 58/393 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TESMIN | c.1222G>T p.E408* | Nonsense Mutation (SNP) | VAF 84/524 reads (16%) | called by muse, mutect2, varscan2
- EIF3L | c.45C>T p.D15= | Silent (SNP) | VAF 258/667 reads (39%) | catalogued as rs1052660684; called by muse, mutect2, varscan2
- SIPA1L3 | c.4347G>A p.Q1449= | Silent (SNP) | VAF 84/314 reads (27%) | called by muse, mutect2, varscan2
